Somatic mutation profile of tumor specimen TCGA-L5-A4OG-01A (aliquot TCGA-L5-A4OG-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OG, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 79.7 years (29,105 days).
Specimen TCGA-L5-A4OG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 761e46bd-aee1-4427-a990-fb2507eb9676.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OG-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OG-11A-12D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9170bbba-4b16-46b8-898e-0097ac4e390c

The open-access MAF lists 163 somatic variants for this specimen: 125 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 35, Nonsense Mutation 9, Frame Shift Del 3, Splice Site 3, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Translation Start Site 1, 5'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPJ | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 17/113 reads (15%) | catalogued as rs797045450; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYNC2H1 | c.10573C>T p.R3525* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs181011657; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 74/197 reads (38%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKAP6 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757619323; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- ART1 | c.649A>G p.T217A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs199558962; called by muse, mutect2, varscan2
- ATP6V0D2 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs745342113, COSV53413418; called by muse, mutect2, varscan2
- ATRN | c.2302G>A p.D768N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV99497394; called by mutect2, varscan2
- BRINP3 | c.1799A>C p.K600T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.102); catalogued as COSV66517281; called by muse, mutect2, varscan2
- CDH4 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758996336, COSV100848215; called by muse, mutect2, varscan2
- CSMD3 | c.5074G>T p.E1692* (on ENST00000297405 / NM_001363185.1; = p.E1588* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV52184409; called by muse, mutect2, varscan2
- CTNNBIP1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs778534202; called by muse, mutect2, varscan2
- CYP11B1 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as rs577746344, COSV52829206; called by muse, mutect2, varscan2
- DNAH17 | c.7378G>A p.G2460S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159615129; called by muse, mutect2, varscan2
- ENKUR | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1031366065, COSV100482203; called by muse, mutect2, varscan2
- FGF14 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.684); catalogued as rs757879324, COSV65935613; called by muse, mutect2, varscan2
- FOLH1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57050648; called by muse, mutect2, varscan2
- GAD2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.255); catalogued as rs1050757379, COSV99393464; called by muse, mutect2
- HEATR5B | c.2508C>T p.G836= | Splice Region (SNP) | VAF 5/19 reads (26%) | catalogued as rs1292172730; called by mutect2, varscan2
- HSPA14 | c.1381-1G>A p.X461_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | catalogued as rs1223079408, COSV65683871; called by muse, mutect2, varscan2
- IFI16 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138795047; called by muse, mutect2, varscan2
- ITGB6 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs755954161; called by muse, mutect2, varscan2
- ITK | c.10T>G p.F4V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV70060734, COSV70062344; called by muse, mutect2, varscan2
- KIAA1522 | c.302C>T p.P101L (on ENST00000373480 / NM_001198972.2; = p.P160L on NM_020888.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs201525668; called by muse, mutect2, varscan2
- KMT2C | c.2915G>A p.G972E | Missense Mutation (SNP) | VAF 15/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51285736; called by muse, mutect2
- LAMB4 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.659); catalogued as rs377732422, COSV52728386; called by muse, mutect2, varscan2
- LMO7 | c.4372G>A p.E1458K (on ENST00000357063; = p.E1139K on NM_005358.5) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1347879930, COSV58533707; called by muse, mutect2
- MRC2 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765734147; called by muse, mutect2, varscan2
- MSN | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417887388, COSV64303309; called by muse, mutect2, varscan2
- MUC16 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1335513253, COSV67490584; called by mutect2, varscan2
- MYH7B | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99482755; called by muse, mutect2
- NEU4 | c.404C>T p.S135L (on ENST00000391969 / NM_001167602.3; = p.S147L on NM_080741.4) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1012494044; called by muse, mutect2, varscan2
- NME8 | c.1210A>G p.R404G | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52254619, COSV99553357, COSV99553951; called by muse, mutect2, varscan2
- NMT1 | c.466T>G p.F156V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51958650; called by muse, mutect2
- NRXN2 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); catalogued as COSV55465758; called by muse, mutect2, varscan2
- OR4A15 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs374555766, COSV59036488; called by muse, mutect2, varscan2
- OS9 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57783115; called by muse, mutect2, varscan2
- PARP3 | c.367_369del p.K123del | In Frame Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1559747197; called by pindel, varscan2
- PCDHB8 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.734); catalogued as rs868969986, COSV50784405; called by muse, mutect2
- PCDHGA3 | c.2257T>C p.Y753H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV54039906; called by muse, mutect2, varscan2
- PIK3C2A | c.3352C>T p.P1118S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1303954156, COSV99791053; called by muse, mutect2, varscan2
- PRAMEF14 | c.1370G>T p.C457F | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1389272298; called by muse, mutect2, varscan2
- PSG8 | c.698T>G p.L233R | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302014848, COSV60613577; called by muse, mutect2, varscan2
- PSKH2 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.401); catalogued as rs201830947; called by muse, mutect2
- RECQL4 | c.2069C>T p.T690M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs369950284; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RIMS2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 62/90 reads (69%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.611); catalogued as COSV68485582; called by muse, mutect2, varscan2
- RP1 | c.5117T>C p.V1706A | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1329756789; called by muse, mutect2, varscan2
- RSPH10B2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.085); catalogued as rs771720978, COSV99786244; called by mutect2, varscan2
- SOBP | c.2599C>T p.R867* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100433269, COSV57995687; called by muse, mutect2, varscan2
- STAB1 | c.3055C>T p.R1019C | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs748986896, COSV58742227; called by muse, mutect2, varscan2
- TENM1 | c.1771G>A p.V591I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs201117886, COSV64445538; called by muse, mutect2, varscan2
- TMF1 | c.289T>G p.F97V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs777661595; called by muse, mutect2, varscan2
- TPD52L1 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs541032352, COSV59190387; called by muse, mutect2, varscan2
- USH2A | c.1336C>G p.P446A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56331241; called by muse, mutect2
- XKR8 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1313565855; called by muse, mutect2, varscan2
- ZMYM3 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587777358, CM144345, COSV58739216; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAP2 | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP15 | c.649A>T p.S217C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- BOD1L1 | c.6314T>C p.M2105T | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- C15orf39 | c.2620C>T p.R874W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1I | c.5852C>A p.P1951Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CDYL2 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- CNEP1R1 | c.368A>C p.H123P (on ENST00000427478 / NM_001281789.1; = p.H140P on NM_153261.5) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- COG5 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- COQ8A | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CREBBP | c.2217G>A p.M739I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by mutect2, varscan2
- CYLC1 | c.1667A>C p.K556T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- CYP3A5 | c.99del p.F33Lfs*57 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- EMCN | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2
- EMCN | c.11T>G p.L4R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EPC2 | c.1387G>T p.D463Y | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GIGYF1 | c.1485G>A p.M495I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- GPR87 | c.871dup p.I291Nfs*16 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | called by mutect2, pindel, varscan2
- GRAP2 | c.397A>G p.R133G | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- HUWE1 | c.2304T>A p.D768E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- IDH3G | c.924+1G>C p.X308_splice | Splice Site (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- INSR | c.2153A>G p.Q718R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITIH1 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- JAG1 | c.2132A>G p.E711G | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIF4A | c.2277A>C p.E759D | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KRTAP19-5 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 20/93 reads (22%) | called by muse, mutect2, varscan2
- LRP8 | c.185_186del p.S62Cfs*9 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by pindel, varscan2
- MYOM1 | c.914A>C p.E305A | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- NAT9 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- NBEA | c.5741T>G p.L1914R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NUP210 | c.4034T>A p.M1345K | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR10H2 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5D13 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8U1 | c.588G>T p.Q196H | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2
- PEG3 | c.4238T>C p.V1413A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- PIK3C2B | c.1382T>C p.L461P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3R6 | c.1975T>A p.L659M | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PKHD1L1 | c.2264C>A p.A755E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.85); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PMS2 | c.2305T>C p.S769P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- POP1 | c.2903C>T p.T968I | Missense Mutation (SNP) | VAF 72/93 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPFIA2 | c.3572T>G p.F1191C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2
- PPP1R3A | c.1547A>G p.D516G | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PRDX4 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPL36AL | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- RYR2 | c.10764T>G p.H3588Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SLC36A3 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SMG9 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.4637C>T p.A1546V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SPRY1 | c.602_609del p.C201Lfs*2 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- SPTBN4 | c.3067C>T p.R1023C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- SSTR3 | c.947T>G p.L316R | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE1 | c.10652C>G p.S3551* (on ENST00000367255 / NM_182961.4; = p.S3558* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- TET1 | c.4766A>C p.K1589T | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TGM6 | c.1968-1G>A p.X656_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- THEMIS2 | c.857G>C p.G286A | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMEM248 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 3/33 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); called by muse, mutect2
- TMX2 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.08); called by muse, mutect2
- TOB1 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- TPRN | c.1502T>C p.F501S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAPPC10 | c.1951T>C p.S651P | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM13 | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- TSGA10 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by mutect2, varscan2
- URB2 | c.3448C>T p.H1150Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ZFP2 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- ZNF208 | c.2663C>A p.P888H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- ZNF337 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF382 | c.1580A>G p.K527R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF563 | c.1346A>C p.N449T | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ZNF804A | c.1855A>G p.K619E | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.63); called by muse, mutect2
- ZNF81 | c.592A>G p.S198G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP5 | c.3237G>A p.L1079= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- CELSR3 | c.1566C>T p.P522= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99373972; called by muse, mutect2, varscan2
- CHRNA7 | c.1179C>T p.D393= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs752171678; called by muse, mutect2, varscan2
- COL6A3 | c.3555C>A p.A1185= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV55095477; called by muse, mutect2, varscan2
- DNAH3 | c.8379C>G p.G2793= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- EVC2 | c.2763G>T p.L921= | Silent (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- FAHD2A | c.849C>T p.V283= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs572805523, COSV51977881; called by muse, mutect2, varscan2
- FAM189A2 | c.1278C>T p.A426= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs748637394, COSV57386358; called by muse, mutect2, varscan2
- FASN | c.2577C>T p.A859= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs778504673, COSV60758216; called by muse, mutect2, varscan2
- FST | c.466C>T p.L156= | Silent (SNP) | VAF 4/19 reads (21%) | called by mutect2, varscan2
- GPC3 | c.1350G>A p.L450= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV100893257; called by muse, mutect2, varscan2
- GPLD1 | c.1380C>T p.N460= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs773527187; called by mutect2, varscan2
- GPR101 | c.1245C>T p.Y415= | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- GPR39 | c.813C>T p.S271= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs558356688; called by muse, mutect2, varscan2
- LIPI | c.541T>C p.L181= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1354436652; called by mutect2, varscan2
- LRG1 | c.570G>A p.L190= | Silent (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- MAP3K11 | c.372C>T p.G124= | Silent (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.16527T>G p.S5509= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV67446521, COSV67464155; called by muse, mutect2, varscan2
- NUGGC | c.780C>T p.A260= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs751273733, COSV58433640; called by muse, mutect2, varscan2
- PCDHB8 | c.2115G>A p.S705= | Silent (SNP) | VAF 40/140 reads (29%) | called by muse, mutect2, varscan2
- POLDIP2 | c.747C>T p.Y249= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- PREX2 | c.4134A>G p.K1378= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV55772082, COSV55807968; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 59/83 reads (71%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- RYR1 | c.7725C>T p.R2575= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1020398192, COSV62099508; ClinVar: likely benign; called by muse, mutect2, varscan2
- SACS | c.12216T>G p.T4072= | Silent (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- SCN2A | c.5115C>A p.I1705= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV51850305, COSV51856999; called by muse, mutect2, varscan2
- SMARCA5 | c.1476C>T p.L492= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- SOX5 | c.639A>G p.R213= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1193948415; called by muse, mutect2, varscan2
- SPIN3 | c.12G>A p.P4= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs753148068, COSV66529222; called by muse, mutect2, varscan2
- SRCAP | c.9069C>T p.P3023= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs747051921, COSV52679581, COSV99349703; called by muse, mutect2, varscan2
- STAU1 | c.1368C>T p.A456= (on ENST00000371856 / NM_001319135.1; = p.A375= on NM_004602.3) | Silent (SNP) | VAF 15/101 reads (15%) | called by muse, mutect2, varscan2
- TEX15 | c.6081T>C p.D2027= (on ENST00000256246; = p.D2410= on NM_001350162.2) | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- TRHDE | c.2424C>T p.Y808= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1375645291; called by muse, mutect2, varscan2
- TRIM24 | c.1776G>A p.T592= (on ENST00000343526 / NM_015905.3; = p.T558= on NM_003852.4) | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs754183037; called by muse, mutect2, varscan2
- ZNF257 | c.340A>C p.R114= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV71306196, COSV71306850; called by muse, mutect2, varscan2
- GNG2 | c.-1G>A | 5'UTR (SNP) | VAF 5/19 reads (26%) | catalogued as rs777396127; called by muse, mutect2, varscan2
- L1CAM | c.-109+697C>G | Intron (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2
- MRPS17P9 | n.64dup | RNA (INS) | VAF 29/78 reads (37%) | called by mutect2, pindel, varscan2
